Somatic mutation profile of tumor specimen TCGA-ZK-AAYZ-01A (aliquot TCGA-ZK-AAYZ-01A-12D-A46P-09) from TCGA case TCGA-ZK-AAYZ, project TCGA-CHOL (Cholangiocarcinoma).
Specimen TCGA-ZK-AAYZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98648c27-6e67-4ddc-8337-7acdd38d68bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZK-AAYZ-10A (Blood Derived Normal), aliquot TCGA-ZK-AAYZ-10A-01D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c6c7b00-a158-473b-b196-0d4f97a6cd88

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 21, Silent 15, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARAP3 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs772289556; called by muse, mutect2, varscan2
- FAM50A | c.986C>G p.P329R | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50133438; called by muse, mutect2, varscan2
- NEURL2 | c.118G>T p.G40W | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV51941894; called by muse, mutect2, varscan2
- NTRK1 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764417252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP2R2B | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs765850208; called by muse, mutect2, varscan2
- SLIT2 | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.97); PolyPhen benign (0.031); catalogued as rs762755360; called by muse, mutect2, varscan2
- SPEF2 | c.1591A>T p.I531L | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV61554229; called by muse, mutect2, varscan2
- SZRD1 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65044169; called by muse, mutect2
- CES3 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DDX10 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DUXA | c.429_430del p.R144Sfs*11 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- FAM135B | c.2504A>G p.D835G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IKZF3 | c.1328del p.N443Tfs*6 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- IPO9 | c.2771A>T p.E924V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF19 | c.2879C>A p.S960Y | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LCN1 | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.167); called by muse, mutect2
- NOS1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NSMF | c.1258C>T p.L420F (on ENST00000371475 / NM_001130969.3; = p.L418F on NM_015537.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- OSBPL8 | c.2619_2621del p.I874del | In Frame Del (DEL) | VAF 17/102 reads (17%) | called by pindel, varscan2
- PDCD10 | c.128C>A p.T43K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- STX12 | c.601A>T p.I201L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SYNM | c.1091C>A p.P364H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- WASF2 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACSF2 | c.33G>A p.G11= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1262507536, COSV55954001; called by muse, mutect2, varscan2
- ASIC5 | c.906C>T p.I302= | Silent (SNP) | VAF 35/101 reads (35%) | called by muse, mutect2, varscan2
- BRAF | c.1101C>T p.P367= | Silent (SNP) | VAF 63/174 reads (36%) | catalogued as rs745898551; called by muse, mutect2, varscan2
- CDH4 | c.549C>T p.R183= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1228050535; called by muse, mutect2
- CDKL1 | c.792C>A p.L264= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- DLG5 | c.405C>A p.P135= | Silent (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- DPYS | c.753C>T p.S251= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- FRMPD3 | c.2742G>T p.L914= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- GPX3 | c.13C>T p.L5= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, varscan2
- LSR | c.264G>A p.R88= | Silent (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- NUP98 | c.1557C>T p.F519= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV61434051; called by muse, mutect2, varscan2
- PER3 | c.1428C>G p.L476= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- PEX5L | c.381G>A p.K127= | Silent (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
- PSME3 | c.699C>T p.D233= | Silent (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- ZFAT | c.3435C>A p.A1145= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
